Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JE, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JE-01A (Primary Tumor).

[page 1 of 3]
Requesting Doctor's Information:

HISTOPATHOLOGY FOR REVIEW

This case was shown at the endocrine clinicopathological meeting. I agree with diagnosis of adrenal cortical carcinoma. The carcinoma is the same as that present in the recurrence from

REPORTING PATHOLOGIST:

(Electronic Signature)

ICD-O-3

Carcinoma, adrenal cortical

8370/3

Site: ④ Adrenal Gland, cortex

874.0

940 1/30/13

P
A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O

[page 2 of 3]
SURGICAL PATHOLOGY

Continued

[page 3 of 3]
Ref:	
Name:	

--

Sex / DOB:	FEMALE
Copies to:	

SURGICAL PATHOLOGY

Received:

IMMUNOCHEMISTRY:

The tumour cells are positive for synaptophysin and melan-A. They are negative for AE1/AE3. They give weak focal staining with CD10. The staining characters are consistent with adrenocortical tumour.

COMMENT:

Frequent mitoses with occasional atypical mitoses, nuclear pleomorphism, endothelial lined space permeation and necrosis are supportive of the diagnosis of carcinoma.

Dr has also seen this case and agrees with the above.

DIAGNOSIS

LEFT ADRENAL MASS: ADRENOCORTICAL CARCINOMA.
(PLEASE SEE COMMENT).

T93000, M80103

(Electronic signature)

Criteria	hw 1/4/13	Yes	No

Source: NCI Genomic Data Commons file 77cb09d5-ad40-4de7-b560-9ea9a37e7972 (TCGA-OR-A5JE.80EDB29A-262A-486D-B31A-EA015FA8A362.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).